Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A8WV, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A8WV-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

ICD-10
Adenocarcinoma NOS 8140/3
Site Prostate H63
W 8/28/14

FINAL PATHOLOGIC DIAGNOSIS

- A. Lymph nodes, right pelvis, dissection: No carcinoma in six lymph nodes (0/6).
- B. Lymph nodes, left pelvis, dissection: Metastatic carcinoma in one of four lymph nodes (1/4).
- C. Prostate and seminal vesicles, radical prostatectomy:
- Prostate:
1. Prostatic adenocarcinoma, Gleason score 4+5=9, with extra-prostatic extension; see comment.
2. Stromal hypertrophy.
- Seminal vesicles: Right seminal vesicle involved by prostatic adenocarcinoma; see comment.

COMMENT:

Synoptic Comment for Prostate Tumors

- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:** Left mid gland, slides C9-C12, C22; left base, slide C20; right posterior mid gland, slides C8, C21.
- **Estimated volume of tumor:** 7.9 cubic cm.
- **Gleason score:** 4+5; primary pattern 4, secondary pattern 5.
- **Estimated volume > Gleason pattern 3:** >90%. (only a minor component of the tumor is Gleason pattern 3).
- **Involvement of capsule:** Tumor invades capsule on left posterior quadrant (slides C11-C12).
- **Extraprostatic extension:** Present, limited in extent.
- **Margin status for tumor:** Negative.
- **Margin status for benign prostate glands:** Benign glands present at inked excision margins; left apex, slide C2 and right and left base, slides C16-C17.
- **High-grade prostatic intraepithelial neoplasia (HGPIN):** Present; focally.

[page 2 of 3]
- **Tumor involvement of seminal vesicle:** Tumor invades into the muscular wall of the right seminal vesicle; slide C21.
- **Perineural infiltration:** Present.
- **Lymph node status:** Positive;
- Total number of positive nodes: 1.
- Total number of nodes examined: 10.
- Size of largest metastasis in node: 0.5 mm.
- Extranodal extension: None.
- **AJCC/UICC stage:** pT3bN1.

has reviewed slides C11 and C21 and agrees with the diagnoses.

Specimen(s) Received

A: Right pelvic lymph nodes

B: Left pelvic lymph nodes

C: Prostate & seminal vesicles (fresh)

Clinical History

The patient is a 68-year-old man with a history of prostate carcinoma, Gleason grade 4/5, clinical stage T3aNxM0. Review of the electronic medical records reveals an elevated PSA of 8.04, which led to subsequent ultrasound-guided needle core biopsies of the prostate at an outside facility, which were reviewed at [redacted] in consultation [redacted]. Subsequent ultrasound performed by [redacted] reveals a large left posterior base nodule suspicious for extracapsular extension. The patient now undergoes robot-assisted radical prostatectomy with bilateral pelvic lymph node dissection.

Gross Description

The specimen is received in three parts, all labeled with the patient's name and unit number. Parts A and B are received in formalin, while Part C is received fresh.

Part A, additionally labeled "right pelvic lymph nodes," consists of multiple, small, soft, irregular, yellow-tan fibrofatty tissue fragments (3.5 x 2.5 x 0.7 cm in aggregate). Careful examination reveals six, soft to firm, yellow-tan lymph node candidates (0.3 cm-1.5 cm). The entire specimen is submitted as follows:

Cassette A1:	One lymph node candidate, bisected.
Cassette A2:	One lymph node candidate, bisected.
Cassette A3:	Two lymph node candidates, intact.
Cassette A4:	Two lymph node candidates, intact.
Cassette A5:	Entire fibrofatty remnant.

Part B, additionally labeled "left pelvic lymph nodes," consists of a single, irregular segment of soft to firm, yellow-tan fibrofatty tissue (6 x 2.5 x 1 cm). Careful examination reveals five soft yellow-tan lymph node candidates (0.4 cm-3 cm). The entire specimen is submitted as follows:

Cassettes B1-B2:	One lymph node candidate, bisected.
Cassette B3:	One lymph node candidate, bisected.
Cassette B4:	Three lymph node candidates, intact.
Cassette B5:	Entire fibrofatty remnant.

Part C, additionally labeled "prostate and seminal vesicles," consists of a single, intact radical prostatectomy (55 gm; 4 cm from apex to base x 5 cm in width x 4 cm from anterior to posterior) with an attached right seminal vesicle bundle and a detached left seminal vesicle/vas deferens bundle.

GROSS PATHOLOGIC FINDINGS: There is a single, poorly defined, irregular, firm, white-tan mass (1.5 x 1.5 x 1.2 cm, slices 6-8, cassettes C11-C12). The tumor abuts the capsule in multiple foci and abuts the inked proximal base margin (adjacent to bladder margin) and demonstrates possible extra-capsular extension in the posterior base margin (adjacent to left seminal vesicle/vas deferens junction). No other masses are identified..

[page 3 of 3]
The remaining peripheral zone is light tan and unremarkable. The central/transitional zone is enlarged and nodular. The anterior fibrous stroma is open and the remaining capsule appears intact. The seminal vesicle/vas deferens bundles (right 3.5 x 2 x 0.5 cm; left 3 x 2.2 x 0.5 cm) are soft and whorled, without direct evidence of tumor extension.

ORIENTED BY: Anatomic landmarks.

INKING: Right anterior surface in green, left anterior surface in blue, posterior surface in black.

POTENTIAL STUDIES: Fresh tissue is harvested for research purposes.

GROSS PHOTOGRAPHS: Yes; slice 7.

TOTAL NUMBER OF SLICES: 8, inclusive of apical margin.

AVERAGE SLICE THICKNESS: 0.5 cm.

CASSETTES: Representative sections are submitted as follows:

Apical margins, entirely submitted in perpendicular sections

C1: Right apex.

C2: Left apex.

Right anterior quadrant

C3: Slice 3.

C4: Slice 5.

C5: Slice 7.

Right posterior quadrant

C6: Slice 3.

C7: Slice 5.

C8: Slice 7.

Left posterior quadrant

C9: Slice 3.

C10: Slice 5.

C11: Slice 7, tumor.

C12: Slice 8, additional posterior and proximal bladder margin (section inked red for identification).

Left anterior quadrant

C13: Slice 3.

C14: Slice 5.

C15: Slice 7.

Bladder margins, entirely submitted in perpendicular sections

C16-B20: Sequentially submitted from right to left.

Prostatic/seminal vesicle junction and cross-section of vas deferens

C21: Right.

C22: Left.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

/Pathologist

Electronically signed out on

Source: NCI Genomic Data Commons file 655915b3-9023-432b-ad9b-97c2b9616735 (TCGA-V1-A8WV.AD602A56-B2CB-49A0-A994-7927600C952B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).